Somatic mutation profile of tumor specimen TCGA-R8-A73M-01A (aliquot TCGA-R8-A73M-01A-11D-A32B-08) from TCGA case TCGA-R8-A73M, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 48.2 years (17,610 days).
Specimen TCGA-R8-A73M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 405c95ea-1097-4899-a0e7-5b1f582a92b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R8-A73M-10C (Blood Derived Normal), aliquot TCGA-R8-A73M-10C-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ab2fb71-9427-4d92-9b25-6511248d7768

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Splice Region 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC8 | c.2760A>T p.E920D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100217332; called by muse, mutect2, varscan2
- ADGRG4 | c.5513A>T p.Y1838F | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99795686; called by muse, mutect2, varscan2
- AOPEP | c.2296G>A p.E766K (on ENST00000375315 / NM_001193329.1; = p.E667K on NM_032823.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as COSV99949706, COSV99949978; called by muse, mutect2, varscan2
- ASTL | c.336C>T p.Y112= | Splice Region (SNP) | VAF 13/29 reads (45%) | catalogued as rs148110898; called by muse, mutect2, varscan2
- CACNA1F | c.3406G>A p.V1136I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs782039374, COSV100544620; called by muse, mutect2, varscan2
- CDK8 | c.697A>G p.I233V | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV101037305; called by muse, mutect2
- CDYL | c.1202G>A p.C401Y (on ENST00000328908 / NM_001368125.1; = p.C347Y on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as rs765086192, COSV100189455; called by muse, mutect2, varscan2
- CIC | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99359685; called by muse, mutect2, varscan2
- DNAH1 | c.11671C>T p.R3891W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774152723, COSV56238105; called by muse, mutect2, varscan2
- DRD3 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99879469; called by muse, mutect2, varscan2
- F5 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778637600, COSV100889125; called by muse, mutect2, varscan2
- FKBP15 | c.1898A>G p.H633R | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.55); catalogued as COSV99439016; called by muse, mutect2, varscan2
- GPR119 | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 111/243 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs768861083, COSV99358639; called by muse, mutect2, varscan2
- HASPIN | c.1113C>A p.D371E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV99561084; called by muse, mutect2, varscan2
- MAP3K12 | c.507G>C p.K169N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.122); catalogued as COSV99913307; called by muse, mutect2, varscan2
- OAS3 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs998990547, COSV99966321; called by muse, mutect2, varscan2
- PAGE1 | c.25T>A p.Y9N | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV65998725, COSV65998947; called by muse, mutect2, varscan2
- POSTN | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101123352, COSV65713866; called by muse, mutect2, varscan2
- RANBP2 | c.2129A>G p.Y710C | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99312255; called by muse, mutect2, varscan2
- RASAL2 | c.1535A>G p.K512R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100862671; called by muse, mutect2, varscan2
- TFAP2D | c.1140-2A>G p.X380_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99145970; called by muse, mutect2
- USP7 | c.583G>C p.V195L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.279); catalogued as COSV100784201; called by muse, mutect2, varscan2
- OR4E2 | c.828del p.V277Wfs*6 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- INSR | c.2745G>T p.G915= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs760446454, COSV100252394; called by muse, mutect2, varscan2
- MUC2 | c.63G>C p.P21= | Silent (SNP) | VAF 63/197 reads (32%) | catalogued as rs575179256; called by muse, mutect2, varscan2
- PCDH19 | c.729C>T p.Y243= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as rs1166554052, CM106011, COSV55266179; called by muse, mutect2, varscan2
- SEMA3A | c.387G>A p.L129= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs762929241, COSV54878159, COSV99546883; called by muse, mutect2, varscan2
- THOC2 | c.3258T>C p.D1086= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV99833479; called by muse, mutect2, varscan2
